Somatic mutation profile of tumor specimen C3N-03878-01 (aliquot CPT0237620010) from CPTAC case C3N-03878, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage III; Tumor grade: G1; Age at diagnosis: 52.9 years (19,338 days).
Specimen C3N-03878-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f9ff957e-3c16-49cc-ab4f-3070d7fd7858.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03878-31 (Blood Derived Normal), aliquot CPT0237680002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/68902b3a-00c7-4db7-94ae-2883dd523195

The open-access MAF lists 97 somatic variants for this specimen: 69 protein-altering or splice-affecting, 18 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 18, Intron 4, 3'UTR 3, Frame Shift Del 2, Frame Shift Ins 2, Nonsense Mutation 2, RNA 1, Splice Region 1, 5'UTR 1, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.6852_6855del p.Y2285Tfs*5 (on ENST00000358273 / NM_001042492.3; = p.Y2264Tfs*5 on NM_000267.3) | Frame Shift Del (DEL) | VAF 37/171 reads (22%) | catalogued as rs1555535032; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.438G>A p.W146* | Nonsense Mutation (SNP) | VAF 91/285 reads (32%) | hotspot (GDC flag); catalogued as rs1131691026, CM101750, COSV52661500, COSV52987374, COSV53571745; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AGRN | c.1004C>T p.P335L | Missense Mutation (SNP) | VAF 246/717 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); catalogued as rs750940251; called by muse, mutect2, varscan2
- ANO1 | c.1286G>A p.R429Q | Missense Mutation (SNP) | VAF 78/2990 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1489451483; called by muse, mutect2
- BARX1 | c.700G>T p.A234S | Missense Mutation (SNP) | VAF 152/626 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as rs1446509008; called by muse, mutect2, varscan2
- BIRC2 | c.163A>G p.T55A | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as rs147638046; called by muse, mutect2, varscan2
- BROX | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 46/316 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.017); catalogued as rs750979939; called by muse, mutect2, varscan2
- CD1D | c.1000G>A p.V334I | Missense Mutation (SNP) | VAF 68/334 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777157013, COSV63808414; called by muse, mutect2, varscan2
- CIT | c.3917C>T p.T1306M | Missense Mutation (SNP) | VAF 70/266 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as rs139699922; called by muse, mutect2, varscan2
- COL4A1 | c.1753C>T p.R585C | Missense Mutation (SNP) | VAF 55/211 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs374223828; called by muse, mutect2, varscan2
- COP1 | c.974T>G p.I325S | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.069); catalogued as rs1213849617, COSV58174237; called by muse, mutect2, varscan2
- CTTN | c.836G>A p.R279K | Missense Mutation (SNP) | VAF 88/2528 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.068); catalogued as rs1341621279; called by muse, mutect2
- FBXO25 | c.929A>G p.K310R (on ENST00000382824 / NM_183421.2; = p.K243R on NM_012173.3) | Missense Mutation (SNP) | VAF 66/383 reads (17%) | SIFT tolerated (0.85); PolyPhen benign (0.013); catalogued as rs1036495621; called by muse, mutect2, varscan2
- HEMGN | c.1397C>T p.P466L | Missense Mutation (SNP) | VAF 55/269 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as rs778076914; called by muse, mutect2, varscan2
- LARS2 | c.1489A>G p.M497V | Missense Mutation (SNP) | VAF 54/146 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs537114579; called by muse, mutect2, varscan2
- MAP1A | c.503G>T p.R168L | Missense Mutation (SNP) | VAF 75/355 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV55809326; called by muse, mutect2, varscan2
- MED23 | c.1613G>A p.S538N | Missense Mutation (SNP) | VAF 49/254 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.768); catalogued as COSV63435169; called by muse, mutect2, varscan2
- NAP1L4 | c.411G>A p.M137I | Missense Mutation (SNP) | VAF 46/179 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as rs1057355276; called by muse, mutect2, varscan2
- NEIL3 | c.124C>T p.L42F | Missense Mutation (SNP) | VAF 97/341 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0.154); catalogued as rs1257115719; called by muse, mutect2, varscan2
- NUDT19 | c.253G>T p.G85W | Missense Mutation (SNP) | VAF 142/545 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV67959574; called by muse, mutect2, varscan2
- OR10R2 | c.207C>G p.I69M | Missense Mutation (SNP) | VAF 52/280 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV63768941; called by muse, mutect2, varscan2
- ORC1 | c.1162A>G p.M388V | Missense Mutation (SNP) | VAF 216/788 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as rs1476760968; called by muse, mutect2, varscan2
- POLR1A | c.232del p.L78Wfs*28 | Frame Shift Del (DEL) | VAF 163/789 reads (21%) | catalogued as COSV55692482; called by mutect2, pindel, varscan2
- PTPRZ1 | c.5390A>G p.Y1797C | Missense Mutation (SNP) | VAF 103/276 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1350411673; called by muse, mutect2, varscan2
- RYR3 | c.5210T>C p.V1737A | Missense Mutation (SNP) | VAF 131/528 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.215); catalogued as rs1283531940; called by muse, mutect2, varscan2
- SAMD7 | c.1144C>A p.Q382K | Missense Mutation (SNP) | VAF 72/371 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.754); catalogued as COSV59417374; called by muse, mutect2, varscan2
- SCAF8 | c.3331G>C p.G1111R | Missense Mutation (SNP) | VAF 56/204 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.284); catalogued as COSV100914098; called by muse, mutect2, varscan2
- SEZ6L | c.323G>T p.R108L | Missense Mutation (SNP) | VAF 99/380 reads (26%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as COSV50657840; called by muse, mutect2, varscan2
- SNTG1 | c.1486G>T p.G496C | Missense Mutation (SNP) | VAF 49/281 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.635); catalogued as COSV52476171; called by muse, mutect2, varscan2
- TBC1D16 | c.1936G>A p.V646M | Missense Mutation (SNP) | VAF 113/415 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs771771239, COSV100016606; called by muse, mutect2, varscan2
- TRIM42 | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 91/543 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs1235611090, COSV53882258; called by muse, mutect2, varscan2
- VENTX | c.268C>T p.R90W | Missense Mutation (SNP) | VAF 136/430 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs748299514, COSV58083989; called by muse, mutect2, varscan2
- ZNF571 | c.628C>A p.L210I | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV60734882; called by muse, mutect2, varscan2
- ADAMTS17 | c.2134A>G p.T712A | Missense Mutation (SNP) | VAF 110/484 reads (23%) | SIFT tolerated (0.97); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- AGO1 | c.131A>T p.E44V | Missense Mutation (SNP) | VAF 212/604 reads (35%) | SIFT tolerated (0.57); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ALDH9A1 | c.733C>G p.Q245E | Missense Mutation (SNP) | VAF 126/530 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ALG3 | c.1199C>T p.P400L | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BAG6 | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 165/653 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C15orf48 | c.219C>A p.F73L | Missense Mutation (SNP) | VAF 91/362 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- CARD9 | c.628-7T>C | Splice Region (SNP) | VAF 147/492 reads (30%) | called by muse, mutect2, varscan2
- CFAP44 | c.3325A>C p.T1109P | Missense Mutation (SNP) | VAF 58/361 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- CMTM5 | c.397G>T p.A133S | Missense Mutation (SNP) | VAF 104/293 reads (35%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- DHX32 | c.986G>C p.C329S | Missense Mutation (SNP) | VAF 51/216 reads (24%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH9 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- E2F4 | c.451+2T>C p.X151_splice | Splice Site (SNP) | VAF 76/288 reads (26%) | called by muse, mutect2, varscan2
- EDNRB | c.44A>G p.K15R | Missense Mutation (SNP) | VAF 85/359 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- FCHO1 | c.791G>A p.G264E | Missense Mutation (SNP) | VAF 69/429 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- GPS2 | c.821dup p.M274Ifs*? | Frame Shift Ins (INS) | VAF 13/44 reads (30%) | called by mutect2, pindel, varscan2
- GRHL2 | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 78/297 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- JAK2 | c.2946A>G p.I982M | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- KIAA1109 | c.8709G>C p.Q2903H | Missense Mutation (SNP) | VAF 111/483 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- KIAA1210 | c.869T>C p.V290A | Missense Mutation (SNP) | VAF 78/159 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- KLF15 | c.1168T>A p.F390I | Missense Mutation (SNP) | VAF 193/485 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- LEMD3 | c.30G>T p.Q10H | Missense Mutation (SNP) | VAF 59/282 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- LEMD3 | c.31C>T p.Q11* | Nonsense Mutation (SNP) | VAF 61/286 reads (21%) | called by muse, mutect2, varscan2
- MROH2B | c.3647C>T p.A1216V | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- MUC12 | c.14486C>T p.S4829F (on ENST00000379442; = p.S4686F on NM_001164462.1) | Missense Mutation (SNP) | VAF 182/908 reads (20%) | SIFT tolerated, low confidence (0.09); called by muse, mutect2, varscan2
- NOTCH3 | c.3701G>A p.C1234Y | Missense Mutation (SNP) | VAF 201/948 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR14A2 | c.715T>C p.C239R | Missense Mutation (SNP) | VAF 41/264 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- PDCD11 | c.3023A>G p.K1008R | Missense Mutation (SNP) | VAF 138/499 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDE3A | c.1838G>T p.S613I | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PITPNM2 | c.682T>A p.W228R | Missense Mutation (SNP) | VAF 31/241 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- PPP1R9A | c.215A>G p.Q72R | Missense Mutation (SNP) | VAF 41/203 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- RIBC2 | c.154C>G p.Q52E | Missense Mutation (SNP) | VAF 20/248 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ROR1 | c.122T>C p.V41A | Missense Mutation (SNP) | VAF 48/233 reads (21%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0); called by muse, mutect2, varscan2
- RTL8C | c.13G>A p.V5M | Missense Mutation (SNP) | VAF 65/100 reads (65%) | SIFT tolerated (0.21); PolyPhen benign (0.02); called by mutect2, varscan2
- TMEM14C | c.104T>C p.V35A | Missense Mutation (SNP) | VAF 139/511 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- TTN | c.62631dup p.Y20878Ifs*8 (on ENST00000591111; = p.Y13454Ifs*8 on NM_003319.4) | Frame Shift Ins (INS) | VAF 92/451 reads (20%) | called by mutect2, pindel, varscan2
- ZNF177 | c.785A>G p.E262G | Missense Mutation (SNP) | VAF 60/234 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- C22orf15 | c.216G>A p.K72= | Silent (SNP) | VAF 136/551 reads (25%) | called by muse, mutect2, varscan2
- CEACAM6 | c.843A>G p.T281= | Silent (SNP) | VAF 91/526 reads (17%) | catalogued as rs781907323; called by muse, mutect2, varscan2
- CELF4 | c.1140C>T p.Y380= | Silent (SNP) | VAF 87/354 reads (25%) | catalogued as rs751698326, COSV100611796; called by muse, mutect2, varscan2
- CTNNA1 | c.2394C>T p.A798= | Silent (SNP) | VAF 126/347 reads (36%) | catalogued as rs752347559; ClinVar: likely benign; called by muse, mutect2, varscan2
- DDX54 | c.2574C>T p.V858= | Silent (SNP) | VAF 134/625 reads (21%) | catalogued as COSV58375974; called by muse, mutect2, varscan2
- EVPLL | c.555C>T p.H185= | Silent (SNP) | VAF 103/288 reads (36%) | catalogued as rs780804947, COSV67685150; called by muse, mutect2, varscan2
- FCRL4 | c.945C>A p.G315= | Silent (SNP) | VAF 105/434 reads (24%) | called by muse, mutect2, varscan2
- GABRA5 | c.990C>T p.F330= | Silent (SNP) | VAF 156/695 reads (22%) | catalogued as rs1417092187, COSV59487726; called by muse, mutect2, varscan2
- ICE1 | c.4950G>T p.L1650= | Silent (SNP) | VAF 92/321 reads (29%) | called by muse, mutect2, varscan2
- KCNT2 | c.3282G>A p.E1094= | Silent (SNP) | VAF 51/248 reads (21%) | catalogued as COSV99656128; called by muse, mutect2, varscan2
- KMT2E | c.984C>T p.F328= | Silent (SNP) | VAF 95/265 reads (36%) | called by muse, mutect2, varscan2
- OR4C15 | c.759C>T p.V253= (on ENST00000314644; = p.V199= on NM_001001920.2) | Silent (SNP) | VAF 78/272 reads (29%) | catalogued as rs147994367, COSV58951874; called by muse, mutect2, varscan2
- PGBD2 | c.1428G>A p.K476= | Silent (SNP) | VAF 218/572 reads (38%) | called by muse, mutect2, varscan2
- PLEKHA5 | c.1074A>G p.A358= | Silent (SNP) | VAF 93/433 reads (21%) | called by muse, mutect2, varscan2
- RXFP3 | c.1107C>T p.Y369= | Silent (SNP) | VAF 173/813 reads (21%) | catalogued as COSV100347386; called by muse, mutect2, varscan2
- SLC25A21 | c.99C>T p.P33= | Silent (SNP) | VAF 25/169 reads (15%) | called by muse, mutect2, varscan2
- TRPC1 | c.1071A>T p.V357= (on ENST00000476941 / NM_001251845.2; = p.V323= on NM_003304.4) | Silent (SNP) | VAF 157/469 reads (33%) | called by muse, mutect2, varscan2
- UBFD1 | c.171C>T p.A57= | Silent (SNP) | VAF 72/289 reads (25%) | called by muse, mutect2, varscan2
- ACSM2A | c.597-235G>A | Intron (SNP) | VAF 27/116 reads (23%) | catalogued as rs763475343; called by muse, mutect2, varscan2
- EDDM13 | chr19:56313291 G>A | 3'Flank (SNP) | VAF 18/107 reads (17%) | catalogued as rs763437142; called by muse, mutect2, varscan2
- ESPNP | n.1807G>A | RNA (SNP) | VAF 106/1338 reads (8%) | catalogued as rs752910028; called by muse, mutect2
- FGF10 | c.*50G>T | 3'UTR (SNP) | VAF 51/222 reads (23%) | called by muse, mutect2, varscan2
- GPC1 | c.167-6103C>T | Intron (SNP) | VAF 106/370 reads (29%) | called by muse, mutect2, varscan2
- KIF5B | c.*2C>A | 3'UTR (SNP) | VAF 29/110 reads (26%) | called by muse, mutect2, varscan2
- PDE2A | c.704-86C>T | Intron (SNP) | VAF 149/431 reads (35%) | called by muse, mutect2, varscan2
- RAB5B | c.-64dup | 5'UTR (INS) | VAF 6/60 reads (10%) | catalogued as rs774396898; called by pindel, varscan2
- RFX5 | c.*29dup | 3'UTR (INS) | VAF 93/414 reads (22%) | called by mutect2, pindel, varscan2
- TTR | c.336+188_336+233del | Intron (DEL) | VAF 44/234 reads (19%) | called by mutect2, pindel
